TCGA case TCGA-N1-A6IA — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Montefiore Medical Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8f4c042c-fbe3-4d0c-b2bd-695bc37483f5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Dead; Days to death: 224 days.

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 41.4 years (15,112 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Uterus; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Tumor depth descriptor: Superficial.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 41.7 years (15,228 days); Days to diagnosis: 116 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Additional pathology findings: Well Differentiated.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 41.7 years (15,228 days); Days to diagnosis: 116 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Additional pathology findings: Well Differentiated.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 116 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 116 days.
- Days to follow up: 124 days; Disease response: With Tumor.
- Days to follow up: 224 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-N1-A6IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-N1-A6IA-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-N1-A6IA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-N1-A6IA-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-N1-A6IA-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Disease multifocal indicator: Yes.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 224 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 224 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 116 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-N1-A6IA-01A-12D-A32H-01): tumor purity 0.67, ploidy 3.24, whole-genome doublings 1.
